Somatic mutation profile of tumor specimen HCM-BROD-0420-C71-02B (aliquot HCM-BROD-0420-C71-02B-11D-A82H-36) from HCMI case HCM-BROD-0420-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 48.3 years (17,653 days).
Specimen HCM-BROD-0420-C71-02B: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 85ce932e-e340-4d1d-9274-b7e41f892ac7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0420-C71-10B (Blood Derived Normal), aliquot HCM-BROD-0420-C71-10B-01D-A82H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0d07df8c-27d3-481e-8a0d-6c0e0d8ff97b

The open-access MAF lists 101 somatic variants for this specimen: 89 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 75, Nonsense Mutation 11, Silent 11, Splice Region 1, RNA 1, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.4600C>T p.R1534* (on ENST00000358273 / NM_001042492.3; = p.R1513* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 34/329 reads (10%) | catalogued as rs760703505, CM941093, COSV62191852; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.959T>C p.L320S | Missense Mutation (SNP) | VAF 37/119 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as CD110181, CM033671, CM1513166, CM992427, COSV64288766, COSV64288772, COSV64297208, COSV64305848; called by muse, mutect2, varscan2
- ABCB1 | c.1795G>A p.A599T | Missense Mutation (SNP) | VAF 34/520 reads (7%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.87); catalogued as rs2235036; called by muse, mutect2
- ACACA | c.2824A>G p.S942G | Missense Mutation (SNP) | VAF 151/611 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.702); catalogued as rs376394653; called by muse, mutect2, varscan2
- ARHGAP5 | c.1465G>A p.E489K | Missense Mutation (SNP) | VAF 28/212 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); catalogued as rs78337553, COSV61533654; called by muse, varscan2
- CLMN | c.1867C>T p.Q623* | Nonsense Mutation (SNP) | VAF 24/480 reads (5%) | catalogued as rs756195517; called by muse, mutect2
- CPAMD8 | c.542C>T p.T181M (on ENST00000651564; = p.T134M on NM_015692.5) | Missense Mutation (SNP) | VAF 68/618 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757227350, COSV52233297; called by muse, mutect2, varscan2
- CSN3 | c.385A>G p.I129V | Missense Mutation (SNP) | VAF 27/554 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs748620098; called by muse, mutect2
- DOCK5 | c.880G>A p.V294I | Missense Mutation (SNP) | VAF 116/517 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs777228860, COSV52409651; called by muse, mutect2
- HECW2 | c.968C>T p.T323M | Missense Mutation (SNP) | VAF 63/265 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as rs778909020, COSV53657649; called by muse, mutect2, varscan2
- KIF26A | c.3914C>T p.P1305L | Missense Mutation (SNP) | VAF 179/716 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.846); catalogued as rs771670278, COSV59469211; called by muse, mutect2, varscan2
- LRRN4 | c.1492C>A p.Q498K | Missense Mutation (SNP) | VAF 62/1037 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as COSV66646228; called by muse, mutect2
- MEFV | c.1091C>T p.P364L | Missense Mutation (SNP) | VAF 29/722 reads (4%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs104895214; ClinVar: not provided; called by muse, mutect2
- MLXIPL | c.2415C>G p.Y805* | Nonsense Mutation (SNP) | VAF 39/905 reads (4%) | catalogued as COSV100515247; called by muse, mutect2
- MYLK | c.3901C>T p.R1301C | Missense Mutation (SNP) | VAF 60/774 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.91); catalogued as rs368321325; ClinVar: uncertain significance; called by muse, mutect2
- MYOM3 | c.4225G>A p.V1409I | Missense Mutation (SNP) | VAF 42/672 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs780604403; called by muse, mutect2
- NF1 | c.4108C>T p.Q1370* | Nonsense Mutation (SNP) | VAF 22/326 reads (7%) | catalogued as rs868573462, CD1311340, CM114621, COSV62192664; called by muse, mutect2
- NOS3 | c.749G>A p.R250H | Missense Mutation (SNP) | VAF 75/758 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1277224565, COSV52497537; called by muse, mutect2, varscan2
- OR2K2 | c.883G>T p.A295S (on ENST00000374428; = p.A266S on NM_205859.2) | Missense Mutation (SNP) | VAF 36/379 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100235286; called by muse, mutect2, varscan2
- PCDHB14 | c.193C>T p.R65W | Missense Mutation (SNP) | VAF 95/441 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); catalogued as rs1554289025; called by muse, mutect2, varscan2
- PLCB2 | c.2098C>T p.R700C | Missense Mutation (SNP) | VAF 36/486 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.189); catalogued as rs1325011113, COSV53036702; called by muse, mutect2
- PLCG2 | c.1691G>A p.R564Q | Missense Mutation (SNP) | VAF 102/445 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as COSV100842532, COSV63867739; called by muse, mutect2, varscan2
- PLEKHG4B | c.2982C>T p.D994= (on ENST00000283426; = p.D1350= on NM_052909.5) | Splice Region (SNP) | VAF 39/376 reads (10%) | catalogued as rs751935586; called by muse, mutect2, varscan2
- POM121L12 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 94/975 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.572); catalogued as COSV68692951, COSV68693360; called by muse, mutect2
- REM2 | c.157C>T p.R53W | Missense Mutation (SNP) | VAF 54/566 reads (10%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs773368193, COSV57465117; called by muse, mutect2
- RP1 | c.1102C>T p.R368* | Nonsense Mutation (SNP) | VAF 79/299 reads (26%) | catalogued as rs1195406064, COSV73140136; called by muse, mutect2, varscan2
- SEPTIN8 | c.1444T>C p.F482L | Missense Mutation (SNP) | VAF 52/855 reads (6%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as rs1196597398; called by muse, mutect2
- SLC7A14 | c.128C>T p.T43M | Missense Mutation (SNP) | VAF 146/610 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.063); catalogued as rs761358624, COSV51584914; called by muse, mutect2, varscan2
- SPATA31E1 | c.309G>T p.E103D | Missense Mutation (SNP) | VAF 15/314 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs1052236008; called by muse, mutect2
- TACC2 | c.1192G>A p.E398K | Missense Mutation (SNP) | VAF 159/417 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as rs757642911, COSV57751654; called by muse, mutect2, varscan2
- TTLL9 | c.113G>T p.R38L | Missense Mutation (SNP) | VAF 31/640 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.093); catalogued as COSV100206887; called by muse, mutect2
- USH2A | c.5104G>A p.V1702M | Missense Mutation (SNP) | VAF 54/347 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.732); catalogued as rs201799575, COSV56324658, COSV56376540; called by muse, mutect2, varscan2
- USP40 | c.3089G>A p.R1030H | Missense Mutation (SNP) | VAF 113/468 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.058); catalogued as rs750860688; called by muse, mutect2, varscan2
- WDR87 | c.247G>A p.V83M | Missense Mutation (SNP) | VAF 132/602 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1157851516; called by muse, varscan2
- ZMYM2 | c.3538C>T p.R1180* | Nonsense Mutation (SNP) | VAF 34/150 reads (23%) | catalogued as rs1247894077, COSV67035495; called by muse, mutect2, varscan2
- ZNF831 | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 156/777 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV64040627; called by muse, varscan2
- AACS | c.1138A>G p.T380A | Missense Mutation (SNP) | VAF 25/530 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.529); called by muse, mutect2
- ATP11A | c.301T>C p.F101L | Missense Mutation (SNP) | VAF 98/261 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BIN3 | c.527A>T p.N176I | Missense Mutation (SNP) | VAF 23/654 reads (4%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2
- C9 | c.823T>A p.S275T | Missense Mutation (SNP) | VAF 47/174 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- CBFA2T2 | c.1793C>G p.A598G | Missense Mutation (SNP) | VAF 105/520 reads (20%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- CDH8 | c.899C>T p.A300V | Missense Mutation (SNP) | VAF 97/425 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- CELSR2 | c.1817A>G p.N606S | Missense Mutation (SNP) | VAF 20/574 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CHADL | c.1541G>A p.G514E | Missense Mutation (SNP) | VAF 167/729 reads (23%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- CNOT6 | c.992T>C p.L331P | Missense Mutation (SNP) | VAF 25/351 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- CNTN6 | c.2428T>A p.S810T | Missense Mutation (SNP) | VAF 36/233 reads (15%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CRISP3 | c.484A>C p.T162P (on ENST00000371159 / NM_001368123.1; = p.T144P on NM_006061.4) | Missense Mutation (SNP) | VAF 58/290 reads (20%) | SIFT tolerated (0.58); PolyPhen benign (0.012); called by muse, varscan2
- CSPG4 | c.6015A>G p.I2005M | Missense Mutation (SNP) | VAF 33/611 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.347); called by muse, mutect2
- CYC1 | c.263A>G p.E88G | Missense Mutation (SNP) | VAF 32/906 reads (4%) | SIFT tolerated (0.88); PolyPhen benign (0.082); called by muse, mutect2
- DLG4 | c.505+1G>A p.X169_splice (on ENST00000399506 / NM_001321075.3; = p.X212_splice on NM_001365.4) | Splice Site (SNP) | VAF 85/332 reads (26%) | called by muse, mutect2, varscan2
- EPHB6 | c.2263G>A p.G755S | Missense Mutation (SNP) | VAF 63/507 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM193B | c.8G>A p.R3Q | Missense Mutation (SNP) | VAF 12/256 reads (5%) | SIFT deleterious, low confidence (0); called by muse, mutect2
- FAM227A | c.374A>G p.K125R | Missense Mutation (SNP) | VAF 28/323 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.448); called by muse, mutect2
- FLG | c.2726C>A p.S909* | Nonsense Mutation (SNP) | VAF 30/756 reads (4%) | called by muse, mutect2
- FRMPD4 | c.934A>T p.S312C | Missense Mutation (SNP) | VAF 104/175 reads (59%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- GABBR2 | c.494A>G p.D165G | Missense Mutation (SNP) | VAF 38/325 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GALNT7 | c.1072T>A p.W358R | Missense Mutation (SNP) | VAF 32/528 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GLI1 | c.1846C>T p.P616S | Missense Mutation (SNP) | VAF 33/807 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.007); called by muse, mutect2
- GPA33 | c.332A>G p.D111G | Missense Mutation (SNP) | VAF 75/450 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HCFC2 | c.2292G>T p.R764S | Missense Mutation (SNP) | VAF 27/389 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- KPNB1 | c.2549G>A p.G850E | Missense Mutation (SNP) | VAF 95/427 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- LBP | c.1132G>A p.V378I | Missense Mutation (SNP) | VAF 96/406 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.029); called by muse, varscan2
- LRP10 | c.173C>G p.T58S | Missense Mutation (SNP) | VAF 33/642 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2
- MAP2K4 | c.50G>A p.G17D | Missense Mutation (SNP) | VAF 34/816 reads (4%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0); called by muse, mutect2
- METAP1D | c.718C>T p.Q240* | Nonsense Mutation (SNP) | VAF 11/289 reads (4%) | called by muse, mutect2
- MROH2B | c.878A>C p.K293T | Missense Mutation (SNP) | VAF 25/419 reads (6%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.503); called by muse, mutect2
- MUC12 | c.14806G>T p.E4936* (on ENST00000379442; = p.E4793* on NM_001164462.1) | Nonsense Mutation (SNP) | VAF 151/598 reads (25%) | called by muse, mutect2, varscan2
- MUC5B | c.8450G>C p.R2817T | Missense Mutation (SNP) | VAF 104/1025 reads (10%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- NHSL1 | c.3185A>G p.E1062G | Missense Mutation (SNP) | VAF 28/635 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2
- OR1R1P | c.8C>T p.P3L | Missense Mutation (SNP) | VAF 95/356 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR5J2 | c.605T>C p.F202S | Missense Mutation (SNP) | VAF 16/525 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.095); called by muse, mutect2
- POTEB3 | c.1527T>A p.N509K | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- PRDM16 | c.2014C>T p.H672Y | Missense Mutation (SNP) | VAF 24/778 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); called by muse, mutect2
- RBM39 | c.668T>G p.I223S | Missense Mutation (SNP) | VAF 106/472 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RSPH10B | c.1658T>G p.M553R | Missense Mutation (SNP) | VAF 16/552 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2
- SDK2 | c.4373C>A p.A1458D | Missense Mutation (SNP) | VAF 166/522 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.515); called by muse, mutect2, varscan2
- SH3TC1 | c.2622G>C p.K874N | Missense Mutation (SNP) | VAF 180/716 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- SLC4A2 | c.202G>C p.E68Q | Missense Mutation (SNP) | VAF 16/428 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- SP4 | c.1442C>A p.S481* | Nonsense Mutation (SNP) | VAF 119/559 reads (21%) | called by muse, mutect2, varscan2
- SYNE1 | c.12098A>G p.H4033R (on ENST00000367255 / NM_182961.4; = p.H3962R on NM_033071.3) | Missense Mutation (SNP) | VAF 10/264 reads (4%) | SIFT tolerated (0.7); PolyPhen benign (0.001); called by muse, mutect2
- TNC | c.2170A>T p.K724* | Nonsense Mutation (SNP) | VAF 34/397 reads (9%) | called by muse, mutect2
- TTN | c.1635G>C p.K545N | Missense Mutation (SNP) | VAF 33/121 reads (27%) | PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TUBGCP6 | c.4591_4602del p.F1531_S1534del | In Frame Del (DEL) | VAF 114/525 reads (22%) | called by mutect2, pindel, varscan2
- WNK3 | c.5224T>C p.Y1742H | Missense Mutation (SNP) | VAF 30/231 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- YTHDC2 | c.4121T>C p.I1374T | Missense Mutation (SNP) | VAF 26/390 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); called by muse, mutect2
- ZFP28 | c.2393G>A p.G798E | Missense Mutation (SNP) | VAF 73/356 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- ZFR2 | c.2376C>G p.I792M | Missense Mutation (SNP) | VAF 187/825 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.45); called by muse, mutect2, varscan2
- ZNF263 | c.995C>T p.P332L | Missense Mutation (SNP) | VAF 158/571 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ZNF747 | c.275C>G p.P92R | Missense Mutation (SNP) | VAF 83/1204 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.014); called by muse, mutect2
- ASPM | c.8901T>C p.C2967= | Silent (SNP) | VAF 16/336 reads (5%) | called by muse, mutect2
- CNTNAP2 | c.1032C>T p.G344= | Silent (SNP) | VAF 45/489 reads (9%) | catalogued as rs142122012, COSV62145397; ClinVar: benign / likely benign; called by muse, mutect2
- DRD1 | c.711C>T p.H237= | Silent (SNP) | VAF 94/399 reads (24%) | catalogued as rs777655360, COSV67104736; called by muse, mutect2, varscan2
- KCNT2 | c.1704G>A p.Q568= | Silent (SNP) | VAF 72/250 reads (29%) | catalogued as COSV54079473; called by muse, mutect2, varscan2
- MAT1A | c.981G>A p.P327= | Silent (SNP) | VAF 22/286 reads (8%) | catalogued as rs149163315; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2
- MUC22 | c.4056C>T p.G1352= | Silent (SNP) | VAF 36/980 reads (4%) | called by muse, mutect2
- OR52K2 | c.225T>A p.L75= | Silent (SNP) | VAF 53/568 reads (9%) | called by muse, mutect2, varscan2
- PCDHGB5 | c.1440C>T p.N480= | Silent (SNP) | VAF 32/730 reads (4%) | catalogued as COSV53920678; called by muse, mutect2
- RNF165 | c.621C>G p.V207= | Silent (SNP) | VAF 20/360 reads (6%) | catalogued as rs778614980, COSV53978654; called by muse, mutect2
- TPTE | c.1302A>G p.Q434= (on ENST00000618007 / NM_199261.4; = p.Q416= on NM_199259.4) | Silent (SNP) | VAF 10/204 reads (5%) | called by muse, mutect2
- ZNF541 | c.795C>T p.P265= | Silent (SNP) | VAF 109/598 reads (18%) | catalogued as rs1380187120, COSV54547773; called by muse, mutect2, varscan2
- C5orf60 | n.2364G>A | RNA (SNP) | VAF 135/560 reads (24%) | catalogued as rs776621362, COSV71508536; called by muse, mutect2, varscan2
